Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A24U, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A24U-01A (Primary Tumor).

Diagnostic Discrepancy		☒

Final Diagnosis

Breast, left, simple mastectomy: Infiltrating ductal carcinoma, with micropapillary differentiation, Nottingham grade III (of III) [tubules 3/3, nuclei 3/3, mitoses 2/3; Nottingham score 8/9], forming multiple (2) masses located in the lower outer quadrant adjacent to prior core biopsy site (3 o' clock--1.1 x 1.0 x 1.0 cm; 4 o' clock--1.6 x 1.5 x 1.5 cm) [AJCC pT1c]. Angiolymphatic invasion is present. The non-neoplastic breast parenchyma shows nonproliferative fibrocystic changes. Biopsy site changes in the upper outer quadrant (status post lumpectomy), negative for residual tumor. Nipple and skin without diagnostic abnormality. Skeletal muscle is present and not involved by tumor. All surgical resection margins, including the deep margin, are negative for tumor (minimum tumor free margin, 0.6 cm, superior anterior margin).

Lymph nodes, left axillary, excision: A single (of 5) left axillary lymph node is positive for metastatic carcinoma. Extranodal extension is present.

ICD-O-3

carcinoma, infiltrating duct, NOS 8500/3

Site: breast, NOS C50.9

fw
4/25/11

Source: NCI Genomic Data Commons file 3306e681-36cb-4c57-8dd3-958e1f9aba32 (TCGA-AR-A24U.B481795F-C52C-4FCE-827A-07991C7A7C2E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).